Surgical pathology report (de-identified scan), TCGA case TCGA-AM-5821, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Cureline, specimen TCGA-AM-5821-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

Index	Specimen label	Clinical Site #	Case #	Ethnicity (Race)	Clinical Diagnosis	DOB (mm/dd/yyyy)	Sex	Date of procurement
1	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	Colorectal cancer	[REDACTED]	[REDACTED]	[REDACTED]
	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	Colorectal cancer	[REDACTED]	[REDACTED]	[REDACTED]

[page 2 of 4]
Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount/per container	Unit
Colon, sigmoid	Primary	Tumor	Tissue	Frozen	cryomold	1	390	mg
Blood	n/a	normal	Blood	Frozen	tube	1	4	ml

[page 3 of 4]
Type of Procurement	Histological description	Grade	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Prior Chemo / Hormonal Th	Chemo / Horm Th Details	Prior Radiation
Surgery	Adenocarcinoma	no data	3	x	0	no	no	no
Blood draw	n/a	n/a	n/a	n/a	n/a	no	no	no

[page 4 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

Cellular Tumor %
70
n/a

Source: NCI Genomic Data Commons file e66edf1d-8d56-4400-b25d-cdc0eaf6cd9e (TCGA-AM-5821.5BA47E48-C3F0-484B-AAB5-23C75CF0CEA4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).